Somatic mutation profile of tumor specimen TCGA-FD-A3SO-01A (aliquot TCGA-FD-A3SO-01A-11D-A22Z-08) from TCGA case TCGA-FD-A3SO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.8 years (25,147 days).
Specimen TCGA-FD-A3SO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd6e64c5-dcfe-4ca4-866a-b615144acb93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SO-10A (Blood Derived Normal), aliquot TCGA-FD-A3SO-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88747b32-264b-47c9-9042-bd3112d6ef86

The open-access MAF lists 411 somatic variants for this specimen: 293 protein-altering or splice-affecting, 111 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 111, Nonsense Mutation 27, Splice Site 5, Splice Region 3, Intron 2, 5'Flank 2, RNA 2, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- RB1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | hotspot (GDC flag); catalogued as rs1131690863, CM941204, COSV57294817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934577, CD941800, CM1411657, CM941332, COSV52682484, COSV52703253, COSV52757928; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 54/198 reads (27%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV50957701, COSV50972369; called by muse, mutect2, varscan2
- ABCA10 | c.4579G>A p.D1527N | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV52223647; called by muse, mutect2, varscan2
- ABCB1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55953347; called by muse, mutect2, varscan2
- ABI2 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV53693057; called by muse, mutect2, varscan2
- ACTN2 | c.1404C>G p.L468= | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as COSV63975628; called by muse, varscan2
- ADAM30 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs1388561274, COSV65561284; called by muse, mutect2, varscan2
- ADAMTS18 | c.1704G>C p.L568F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.096); catalogued as rs771883432, COSV51416959; called by muse, mutect2
- ADAMTSL5 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV57860739; called by muse, mutect2, varscan2
- ADCY10 | c.3708G>A p.M1236I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63241346; called by muse, mutect2, varscan2
- ADCY2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100602248; called by muse, mutect2
- ADGRB3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as COSV65399882; called by muse, mutect2, varscan2
- ADGRD1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55447545; called by muse, mutect2, varscan2
- ADGRG4 | c.2193G>C p.L731F | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV54958225; called by muse, mutect2, varscan2
- AFF4 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.988); catalogued as COSV54795611; called by muse, mutect2, varscan2
- AGL | c.3143G>T p.C1048F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV54053582; called by muse, mutect2, varscan2
- AKAP8L | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV68473565, COSV68473613; called by muse, mutect2, varscan2
- ALG1L | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61076032; called by muse, mutect2, varscan2
- AMER3 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58467370; called by muse, mutect2, varscan2
- ANKRD13A | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs1333719473; called by muse, mutect2, varscan2
- ANKRD44 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV56557072; called by muse, mutect2
- ANKRD6 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV60232326; called by muse, mutect2, varscan2
- ANKS1A | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64461348; called by muse, mutect2, varscan2
- AP3B1 | c.2186G>C p.G729A | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54885401; called by muse, mutect2
- AREL1 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62666202, COSV62666697; called by muse, mutect2, varscan2
- ARHGAP12 | c.2309G>T p.R770I | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV60963889; called by muse, mutect2, varscan2
- ARL6IP6 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV58442997; called by muse, mutect2, varscan2
- ARPC5 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54171755; called by muse, mutect2, varscan2
- ASH1L | c.6589G>A p.D2197N (on ENST00000368346 / NM_001366177.2; = p.D2192N on NM_018489.3) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.876); catalogued as COSV64208923; called by muse, mutect2, varscan2
- ASXL1 | c.3806C>T p.S1269L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs747065583, COSV60109567; called by muse, mutect2, varscan2
- ATF6B | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV64352034; called by muse, mutect2, varscan2
- ATP1A2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs181618883, COSV63404142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1B1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs200839517, COSV52269890, COSV99314546; called by muse, mutect2, varscan2
- ATP8B1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52175717, COSV52176588; called by muse, mutect2, varscan2
- B3GAT2 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57771542; called by muse, mutect2, varscan2
- BAG1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV65651663; called by muse, mutect2, varscan2
- BBS4 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51438330; called by muse, mutect2, varscan2
- BLOC1S6 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs149605903; called by muse, mutect2, varscan2
- BRDT | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.36); catalogued as COSV62865365; called by muse, mutect2, varscan2
- C11orf24 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.858); catalogued as rs773839369, COSV58505778; called by muse, mutect2, varscan2
- C3 | c.4772G>A p.R1591K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.922); catalogued as COSV55574352; called by muse, mutect2, varscan2
- C8orf34 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs759635250, COSV61382468; called by muse, mutect2, varscan2
- CALN1 | c.125G>A p.R42Q (on ENST00000329008 / NM_001017440.3; = p.R84Q on NM_031468.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as rs376691632; called by muse, varscan2
- CAPN3 | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV55517547; called by muse, mutect2, varscan2
- CAPN5 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53688640; called by muse, varscan2
- CCDC148 | c.672G>C p.L224F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51762241; called by muse, mutect2, varscan2
- CCDC63 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV57528922; called by muse, mutect2, varscan2
- CCNA1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV55222055; called by muse, mutect2
- CDH9 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as COSV50299652, COSV50382698; called by muse, mutect2, varscan2
- CDKN1B | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 58/107 reads (54%) | catalogued as COSV57430316; called by muse, mutect2, varscan2
- CEP152 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV57860243; called by muse, mutect2, varscan2
- CFAP44 | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as rs1344589180; called by muse, mutect2, varscan2
- CFHR2 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV66381302; called by muse, mutect2, varscan2
- CHRD | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV52608986, COSV52610032; called by muse, mutect2, varscan2
- CHRNA4 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778087682, COSV64717737; called by muse, mutect2, varscan2
- CHUK | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64918029; called by muse, mutect2
- CLUL1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58112237; called by muse, mutect2, varscan2
- CNOT3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV55364075; called by muse, mutect2, varscan2
- CNPPD1 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV55407864; called by muse, mutect2, varscan2
- CTR9 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63728711, COSV63728839; called by muse, mutect2, varscan2
- DAB1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as COSV100140945, COSV59729385; called by muse, mutect2
- DENND4A | c.3182G>A p.G1061E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV71265983; called by muse, mutect2, varscan2
- DHDH | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55482352; called by muse, mutect2, varscan2
- DIDO1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs770549757, COSV56623373, COSV56627673; called by muse, mutect2, varscan2
- DMRT3 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1303470760, COSV51905117; called by muse, mutect2, varscan2
- DNTTIP2 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as COSV63284186; called by muse, varscan2
- ECM1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs200366841, COSV60873353; called by muse, mutect2, varscan2
- ECT2L | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62884917; called by muse, mutect2, varscan2
- EDIL3 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56901791; called by muse, mutect2, varscan2
- EED | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54556053; called by muse, mutect2, varscan2
- EML3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs199907407; called by muse, mutect2, varscan2
- EPB41L5 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as COSV55353186, COSV55355859; called by muse, mutect2, varscan2
- ERN2 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV56833861, COSV56834411; called by muse, mutect2, varscan2
- ESPL1 | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV57759965; called by muse, mutect2, varscan2
- ETV2 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55837913; called by muse, mutect2, varscan2
- ETV3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV58748146; called by muse, mutect2, varscan2
- EXTL2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV64473108; called by muse, mutect2, varscan2
- FAM110B | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.103); catalogued as rs771272946, COSV64065706; called by muse, mutect2, varscan2
- FAM155A | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1160566710, COSV65561070, COSV65564477; called by muse, mutect2, varscan2
- FAM71F1 | c.320C>G p.S107W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780224856, COSV59373876; called by muse, mutect2, varscan2
- FAP | c.414-1G>C p.X138_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV51862681; called by muse, mutect2, varscan2
- FAT2 | c.6278C>A p.S2093Y | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55814265, COSV55821284; called by muse, mutect2, varscan2
- FER1L5 | c.4834C>T p.H1612Y (on ENST00000623019; = p.H1585Y on NM_001293083.2) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as COSV67606286; called by muse, mutect2, varscan2
- FLYWCH1 | c.1166G>A p.R389K (on ENST00000253928 / NM_001308068.2; = p.R388K on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs369027449; called by muse, mutect2, varscan2
- FMO3 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV63006829, COSV63007533; called by muse, mutect2, varscan2
- FOXD2 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58304213; called by muse, mutect2, varscan2
- FOXK2 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV58879652; called by muse, mutect2
- FRAS1 | c.1595G>C p.R532T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs774543368, COSV53617155; called by muse, mutect2, varscan2
- GFRA1 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs1222554599, COSV62606884; called by muse, mutect2, varscan2
- GHRHR | c.1149G>A p.V383= | Splice Region (SNP) | VAF 10/57 reads (18%) | catalogued as rs1275533432, COSV58196290; called by muse, mutect2, varscan2
- GOLGA3 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs375782880; called by muse, mutect2, varscan2
- GON4L | c.1227G>C p.L409F | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.897); catalogued as COSV55195299; called by muse, mutect2, varscan2
- GRIP2 | c.964G>A p.E322K (on ENST00000619221; = p.E225K on NM_001080423.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.424); catalogued as rs766014324, COSV56122083; called by muse, mutect2, varscan2
- GTF2I | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60401657; called by muse, mutect2, varscan2
- HADHA | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV66107639; called by muse, mutect2, varscan2
- HADHB | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs996233345, COSV58545776; called by muse, mutect2, varscan2
- HAUS3 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1417250387, COSV54722931; called by muse, mutect2, varscan2
- HGS | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs746231981, COSV61268291; called by muse, mutect2, varscan2
- HLA-E | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64927565; called by muse, mutect2, varscan2
- HSD3B2 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65593387; called by muse, mutect2, varscan2
- HSD3B2 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV65593392; called by muse, mutect2, varscan2
- IFT88 | c.1714G>A p.E572K (on ENST00000319980 / NM_001318493.2; = p.E563K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60674094; called by muse, mutect2, varscan2
- IGHV3-33 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.038); catalogued as rs753354905; called by muse, mutect2, varscan2
- IGSF10 | c.3872T>A p.F1291Y | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.184); catalogued as rs750338336, COSV56786496; called by muse, mutect2, varscan2
- IL36A | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.307); catalogued as COSV52083278; called by muse, mutect2, varscan2
- INPP5D | c.2550G>C p.E850D (on ENST00000445964 / NM_001017915.3; = p.E849D on NM_005541.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV64037702; called by muse, mutect2, varscan2
- IPO13 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64894471; called by muse, mutect2
- IRX1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.154); catalogued as COSV57359974; called by muse, mutect2, varscan2
- ITIH4 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357307837, COSV56575103; called by muse, mutect2, varscan2
- KCNIP2 | c.766G>T p.D256Y (on ENST00000356640 / NM_173191.3; = p.D271Y on NM_014591.5) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53307394; called by muse, mutect2, varscan2
- KCNIP2 | c.688G>C p.E230Q (on ENST00000356640 / NM_173191.3; = p.E245Q on NM_014591.5) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53307406; called by muse, mutect2, varscan2
- KCNIP2 | c.280G>C p.E94Q (on ENST00000356640 / NM_173191.3; = p.E109Q on NM_014591.5) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs768239994, COSV53307437; called by muse, mutect2, varscan2
- KCNT2 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54075803, COSV54084299; called by muse, mutect2, varscan2
- KCTD16 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV72579216; called by muse, mutect2, varscan2
- KDM1B | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV52808617; called by muse, mutect2, varscan2
- KIF18A | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54183926; called by muse, mutect2
- KIF23 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV52978919; called by muse, mutect2, varscan2
- KIF23 | c.2449G>A p.D817N (on ENST00000260363; = p.D713N on NM_004856.7) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV52980471; called by muse, mutect2, varscan2
- KLF1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV53435158; called by muse, mutect2, varscan2
- KLF4 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV65929062; called by muse, mutect2, varscan2
- KLHL14 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV63833085; called by muse, mutect2, varscan2
- KRT15 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1445365258, COSV54178622; called by muse, mutect2, varscan2
- LAMA1 | c.6920C>T p.S2307F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67532292; called by muse, mutect2, varscan2
- LAYN | c.851G>A p.G284E (on ENST00000375615 / NM_001258390.1; = p.G276E on NM_178834.5) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1565276970, COSV65104920; called by muse, mutect2, varscan2
- LBH | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as rs760642339, COSV68049576; called by muse, mutect2, varscan2
- LGALS12 | c.647A>G p.H216R | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.085); catalogued as rs1371730187; called by muse, mutect2
- LIG4 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV63596597; called by muse, varscan2
- LRP1B | c.1399C>G p.Q467E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV67230466; called by muse, mutect2, varscan2
- LRPPRC | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV53239335; called by muse, mutect2, varscan2
- LRRC37A3 | c.2950C>G p.L984V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59761890; called by muse, mutect2, varscan2
- LRRC7 | c.2572C>T p.P858S (on ENST00000651989 / NM_001370785.2; = p.P825S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV50474222; called by muse, mutect2, varscan2
- MACF1 | c.11972G>C p.G3991A (on ENST00000372915; = p.G1924A on NM_012090.5) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV57125504; called by muse, varscan2
- MACF1 | c.12115G>C p.E4039Q (on ENST00000372915; = p.E1972Q on NM_012090.5) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV57125528; called by muse, varscan2
- MACF1 | c.12208G>A p.E4070K (on ENST00000372915; = p.E2003K on NM_012090.5) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV57125561; called by muse, mutect2, varscan2
- MAGEC1 | c.2941G>C p.D981H | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV53574204; called by muse, mutect2, varscan2
- MAML2 | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73263737; called by muse, varscan2
- MAP2 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV52294059; called by muse, mutect2, varscan2
- MAPK8 | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV64409515; called by muse, mutect2, varscan2
- MRNIP | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV52973457, COSV52974235; called by muse, mutect2, varscan2
- MROH5 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.765); catalogued as COSV71301780; called by muse, mutect2, varscan2
- MRPL38 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53933410; called by muse, mutect2
- MSR1 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV50514419; called by muse, mutect2, varscan2
- MSTO1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV55472236; called by muse, mutect2, varscan2
- MTCL1 | c.5080G>A p.E1694K (on ENST00000306329 / NM_001378206.1; = p.E1375K on NM_015210.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780010644, COSV60407017; called by muse, mutect2, varscan2
- MTRR | c.817C>T p.P273S (on ENST00000264668; = p.P246S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV52944477; called by muse, varscan2
- MTRR | c.1604C>T p.S535F (on ENST00000264668; = p.S508F on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV52944485; called by muse, mutect2, varscan2
- MTX1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs752545512, COSV57426953; called by muse, mutect2
- MUC16 | c.29809G>A p.E9937K | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.019); catalogued as COSV67472039; called by muse, mutect2, varscan2
- MXRA5 | c.4165G>A p.G1389R | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54238169; called by muse, mutect2, varscan2
- NF2 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | catalogued as COSV58526414, COSV58527368, COSV58531117; called by muse, mutect2, varscan2
- NFATC2 | c.131-1G>A p.X44_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV65356945; called by muse, mutect2, varscan2
- NID2 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV53495940, COSV53497551; called by muse, mutect2, varscan2
- NIPA1 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61680055; called by muse, mutect2, varscan2
- NKTR | c.3403G>C p.D1135H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV51772466; called by muse, mutect2, varscan2
- NMBR | c.305C>G p.S102W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57800591, COSV57801558; called by muse, mutect2, varscan2
- NUDT6 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV52650472; called by muse, mutect2, varscan2
- NUP43 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61190176; called by muse, mutect2, varscan2
- NUP58 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV67751431; called by muse, mutect2, varscan2
- OR10S1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1294874537, COSV73342830; called by muse, mutect2, varscan2
- OR2M5 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 120/487 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV63546421; called by muse, mutect2, varscan2
- OR4B1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58883084; called by muse, mutect2, varscan2
- OR52E4 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100389299, COSV57625098; called by muse, mutect2, varscan2
- OR6C65 | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV65568779; called by muse, mutect2, varscan2
- PARP1 | c.1678G>C p.V560L | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV64690469, COSV64690839; called by muse, mutect2, varscan2
- PARP4 | c.3553G>C p.E1185Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67962435; called by muse, mutect2, varscan2
- PARP8 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV55861037; called by muse, mutect2, varscan2
- PCBP4 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs774406552, COSV59054873; called by muse, mutect2, varscan2
- PCSK4 | c.591C>T p.N197= | Splice Region (SNP) | VAF 7/10 reads (70%) | catalogued as rs1373497248; called by muse, mutect2, varscan2
- PDE11A | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as rs1197698140; called by muse, mutect2, varscan2
- PDE4B | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750670488, COSV58480136; called by muse, mutect2, varscan2
- PHF3 | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV50321570; called by muse, mutect2, varscan2
- PHKG2 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60312358, COSV60313097; called by muse, mutect2, varscan2
- PHYKPL | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57424596; called by muse, mutect2, varscan2
- PIKFYVE | c.2599C>G p.Q867E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100010933, COSV52242799; called by muse, mutect2, varscan2
- PLA2R1 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV51780246; called by muse, varscan2
- PLCXD3 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60610063; called by muse, varscan2
- PPP1R16B | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs1475151169; called by muse, mutect2, varscan2
- PPRC1 | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs1382983899, COSV53385981; called by muse, mutect2, varscan2
- PRB2 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV101231458, COSV66982455; called by muse, mutect2, varscan2
- PRDX6 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61165634; called by muse, mutect2, varscan2
- PRG4 | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.54); catalogued as COSV63355732; called by muse, mutect2, varscan2
- PRKCD | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.771); catalogued as COSV57849107; called by muse, mutect2, varscan2
- PRRC2A | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65687145; called by muse, mutect2, varscan2
- PSG3 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 112/414 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV59504813; called by muse, mutect2, varscan2
- PTH2R | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV55916763; called by muse, mutect2, varscan2
- PTPN20 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV99886359; called by muse, mutect2, varscan2
- PTPN22 | c.1267G>A p.E423K (on ENST00000359785 / NM_001193431.2; = p.E368K on NM_012411.5) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.059); catalogued as COSV63084393, COSV63085405; called by muse, mutect2, varscan2
- PTPRD | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61954112, COSV61963091; called by muse, mutect2, varscan2
- PXDC1 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as rs200793898, COSV66661629, COSV66661669; called by muse, mutect2, varscan2
- R3HCC1L | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100107047, COSV54402162; called by muse, mutect2, varscan2
- RAD23B | c.88_96del p.I30_S32del | In Frame Del (DEL) | VAF 15/68 reads (22%) | catalogued as COSV63658849; called by mutect2, pindel, varscan2
- RALGAPA2 | c.2690A>T p.D897V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV52500308; called by muse, mutect2, varscan2
- RANBP3L | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as COSV56954294; called by muse, mutect2, varscan2
- RAP1GAP2 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.432); catalogued as COSV54579775; called by muse, mutect2, varscan2
- RB1 | c.2501C>G p.S834* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | catalogued as CM144782, CM952105, COSV57310865, COSV99925872; called by muse, mutect2, varscan2
- RC3H1 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51202474; called by muse, mutect2, varscan2
- RFX6 | c.1425G>C p.Q475H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60585951; called by muse, mutect2, varscan2
- RFX6 | c.2686C>G p.Q896E | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV60585961; called by muse, mutect2, varscan2
- RGL1 | c.787C>T p.R263* (on ENST00000360851 / NM_001297672.2; = p.R298* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV58980772; called by muse, mutect2, varscan2
- RGMB | c.958G>A p.E320K (on ENST00000513185 / NM_001366508.1; = p.E361K on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57565958; called by muse, mutect2, varscan2
- RHCE | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1053346; called by muse, mutect2, varscan2
- RHOA | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV69042644; called by muse, varscan2
- RPS4Y2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV56488362; called by mutect2, varscan2
- RRAGB | c.1093G>A p.D365N (on ENST00000262850 / NM_016656.4; = p.D337N on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs775130634, COSV53330067, COSV53331513; called by muse, mutect2, varscan2
- SATB2 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs776611711, COSV53485463; called by muse, mutect2, varscan2
- SCN2A | c.4775T>C p.I1592T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.846); catalogued as rs199641159, COSV51844225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.3920G>C p.R1307T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51812380; called by muse, mutect2
- SCUBE1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV62613095; called by muse, mutect2
- SEC16A | c.4345C>T p.H1449Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51526894; called by muse, mutect2, varscan2
- SLC25A2 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV53404076; called by muse, mutect2, varscan2
- SLC27A5 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54020077; called by muse, mutect2, varscan2
- SLC28A3 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs542312574, COSV66152213, COSV66153787; called by muse, mutect2, varscan2
- SLC6A11 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV54394494; called by muse, mutect2, varscan2
- SLC9A6 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV65788154; called by muse, mutect2, varscan2
- SLITRK1 | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65676126; called by muse, mutect2, varscan2
- SNRPB2 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV55719204; called by muse, mutect2, varscan2
- SNX25 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53015165; called by muse, varscan2
- SPO11 | c.581G>C p.C194S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61995961; called by muse, mutect2, varscan2
- SPTA1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV63754563; called by mutect2, varscan2
- SS18L2 | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV50620920; called by muse, mutect2, varscan2
- STK24 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64823058; called by muse, mutect2, varscan2
- STMN3 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1363531575, COSV64246672, COSV64246769, COSV64246872; called by muse, mutect2, varscan2
- SYCP2 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs374298885; called by muse, mutect2, varscan2
- SYNE2 | c.20101G>C p.E6701Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV59953794; called by muse, mutect2
- TEFM | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs748277289, COSV58975018; called by muse, mutect2, varscan2
- TENM2 | c.7865T>C p.V2622A (on ENST00000518659 / NM_001122679.2; = p.V2383A on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV69132409; called by mutect2, varscan2
- TENM3 | c.6577G>A p.E2193K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV69310345; called by muse, mutect2, varscan2
- TGS1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs754206400, COSV52700594; called by muse, mutect2, varscan2
- THBS2 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV64679483; called by muse, mutect2, varscan2
- THG1L | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV51453042; called by muse, mutect2, varscan2
- TICRR | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as rs766513294, COSV51542311; called by muse, mutect2, varscan2
- TLN2 | c.3508G>C p.E1170Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV60890698; called by muse, mutect2, varscan2
- TLR5 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV60559362; called by muse, mutect2, varscan2
- TMEM121B | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as rs1188559136, COSV58898359; called by muse, mutect2
- TMEM131 | c.4564A>G p.K1522E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs184780740, COSV51777727; called by muse, mutect2, varscan2
- TMEM132E | c.1252G>C p.E418Q (on ENST00000321639; = p.E508Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763466562, COSV58697753; called by muse, mutect2, varscan2
- TNFSF13B | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV65516380; called by muse, mutect2, varscan2
- TNXB | c.8197C>T p.R2733W (on ENST00000647633; = p.R2486W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752650618, COSV64480435; called by muse, mutect2, varscan2
- TNXB | c.7208G>C p.G2403A (on ENST00000647633; = p.G2156A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.889); catalogued as COSV64480443; called by muse, mutect2, varscan2
- TPR | c.3484C>G p.Q1162E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1387480848, COSV66602043; called by muse, mutect2, varscan2
- TSPAN33 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV56826609; called by muse, mutect2, varscan2
- TTN | c.15839C>G p.S5280C (on ENST00000591111; = p.S4353C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/215 reads (28%) | PolyPhen probably damaging (0.927); catalogued as COSV59971574, COSV60114759; called by muse, mutect2, varscan2
- TXNIP | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65220646; called by muse, mutect2, varscan2
- UBQLNL | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100975779, COSV66493102; called by muse, mutect2, varscan2
- UBR1 | c.3550C>T p.H1184Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs767690691, COSV51930813; called by muse, mutect2, varscan2
- UIMC1 | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.366); catalogued as COSV65893781; called by muse, mutect2
- USP34 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV68402093, COSV68404411; called by muse, mutect2, varscan2
- USP40 | c.2274G>C p.Q758H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV52482170; called by muse, varscan2
- VCAN | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54107130; called by muse, mutect2, varscan2
- WDPCP | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs746369214, COSV55421781; called by muse, mutect2, varscan2
- WWTR1 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV62291577; called by muse, mutect2, varscan2
- XAF1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV60972192; called by muse, mutect2, varscan2
- YAP1 | c.1231C>T p.R411* (on ENST00000282441 / NM_001130145.3; = p.R357* on NM_006106.5) | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56773000; called by muse, mutect2, varscan2
- ZBTB49 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as COSV61925256; called by muse, mutect2, varscan2
- ZFYVE16 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); catalogued as COSV62016015; called by muse, mutect2, varscan2
- ZMPSTE24 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs267607181, CM093596, COSV101031831, COSV65639581; called by muse, mutect2, varscan2
- ZMYND8 | c.1017C>G p.F339L (on ENST00000311275 / NM_001363741.2; = p.F359L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.443); catalogued as COSV53689245; called by muse, mutect2, varscan2
- ZNF257 | c.1426C>G p.Q476E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs370936676; called by muse, mutect2, varscan2
- ZNF441 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV63540041; called by muse, mutect2
- ZNF445 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV68538997; called by muse, mutect2, varscan2
- ZNF462 | c.3812C>T p.S1271L | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52934758; called by muse, mutect2, varscan2
- ZNF548 | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV60241136, COSV60241609; called by muse, mutect2, varscan2
- ZNF75D | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66132847; called by muse, mutect2
- ZNF93 | c.660G>C p.K220N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV59376012; called by muse, mutect2, varscan2
- ZSCAN31 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs532664988, COSV60181078; called by muse, varscan2
- ADAMTS12 | c.2631C>A p.C877* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- CD163L1 | c.3410-1G>A p.X1137_splice | Splice Site (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- CDKN1A | c.322dup p.E108Gfs*21 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- EP300 | c.4001_4003del p.E1334del | In Frame Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- IFNGR2 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- KIRREL3 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRT8 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- LY96 | c.22del p.S8Pfs*45 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- PBRM1 | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PDE11A | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2
- PIR | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- PSIP1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.037); called by muse, mutect2
- RBMY1E | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- STK31 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- TBC1D14 | c.1648-1G>A p.X550_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- TDRD9 | c.2525C>T p.S842L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- TENT2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- THAP12 | c.319-1G>C p.X107_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- TJP1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- TMCC1 | c.1606A>T p.K536* (on ENST00000393238 / NM_001349268.2; = p.K212* on NM_015008.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- UBE3A | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 50/208 reads (24%) | called by muse, mutect2
- ZC3H13 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- A2M | c.3972C>G p.L1324= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as COSV59387968; called by muse, mutect2, varscan2
- ADAMTS5 | c.2112G>A p.V704= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as rs1438273510, COSV53179957; called by muse, mutect2, varscan2
- ADRM1 | c.99G>A p.L33= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as rs144780505, COSV53387027; called by muse, mutect2, varscan2
- AKAP12 | c.2178C>T p.D726= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as rs754437547, COSV53576358; called by muse, mutect2, varscan2
- AL031777.2 | c.72C>G p.L24= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs150465023; called by muse, mutect2, varscan2
- ALPG | c.1467C>G p.P489= | Silent (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- ANKRD35 | c.3005G>A p.*1002= | Silent (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- ASTN1 | c.3684C>G p.L1228= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV62498284; called by muse, mutect2, varscan2
- ATG2A | c.3702C>G p.L1234= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV65967114; called by muse, mutect2, varscan2
- ATP2B4 | c.3099C>T p.L1033= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as COSV58178965; called by muse, mutect2, varscan2
- BRINP1 | c.2232G>A p.L744= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs1259304910, COSV56302320; called by muse, mutect2, varscan2
- BRINP1 | c.1464G>A p.L488= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1271319023, COSV56302331; called by muse, mutect2, varscan2
- C9orf72 | c.618C>G p.L206= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV66154791; called by muse, mutect2, varscan2
- CACNA1F | c.4866G>A p.R1622= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59904952; called by muse, mutect2, varscan2
- CACNA1G | c.5448C>T p.D1816= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1347603675; called by muse, mutect2
- CCDC88C | c.714C>T p.P238= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV66238836; called by muse, mutect2, varscan2
- CEP97 | c.1125G>A p.T375= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs776938685, COSV59123493; called by muse, mutect2, varscan2
- CHIT1 | c.684C>G p.L228= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV55147284; called by muse, mutect2, varscan2
- CHST6 | c.360C>G p.L120= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV60000624; called by muse, mutect2, varscan2
- CILK1 | c.1905C>T p.Y635= (on ENST00000350082 / NM_001375397.1; = p.Y628= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as rs1482268900, COSV63153849; called by muse, mutect2
- CRTAC1 | c.162C>G p.L54= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV54003042; called by muse, mutect2, varscan2
- CSNK1D | c.81G>A p.T27= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs775019767, COSV58364949; called by muse, mutect2, varscan2
- CYB561 | c.186C>A p.I62= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV62539817; called by muse, mutect2, varscan2
- EPHA4 | c.1296C>T p.V432= | Silent (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- EPOR | c.1020G>A p.G340= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs763619208, COSV55800581; called by muse, mutect2, varscan2
- FCN1 | c.9G>C p.L3= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV65662511; called by muse, mutect2, varscan2
- FGD3 | c.1500G>A p.T500= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1432723006, COSV61596934, COSV61597917; called by muse, mutect2, varscan2
- GBP5 | c.42C>T p.I14= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as rs372467199, COSV100599978; called by muse, mutect2, varscan2
- GOLGB1 | c.5244G>A p.E1748= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV61466633; called by muse, mutect2, varscan2
- GPC5 | c.825C>G p.L275= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV65603509; called by muse, mutect2
- GPR101 | c.660G>A p.R220= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as COSV53239112; called by muse, mutect2, varscan2
- IGSF11 | c.414C>T p.L138= (on ENST00000393775 / NM_001015887.3; = p.L137= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV61168974; called by muse, mutect2, varscan2
- IL12RB1 | c.1521C>T p.L507= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs778329113, COSV74045550; called by muse, mutect2, varscan2
- INHBA | c.252G>A p.L84= | Silent (SNP) | VAF 145/502 reads (29%) | catalogued as COSV54219362, COSV54222117; called by muse, mutect2, varscan2
- ITGAL | c.1380C>T p.F460= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs547379546, COSV63322602; called by muse, mutect2, varscan2
- KATNAL1 | c.1389G>A p.L463= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV66063503; called by muse, mutect2, varscan2
- KCNA3 | c.1173G>C p.L391= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV63901784, COSV63902168; called by muse, mutect2, varscan2
- KDM4C | c.3147G>A p.Q1049= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV67187464; called by muse, mutect2, varscan2
- KLHL18 | c.1518G>C p.L506= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs535735537, COSV51746223; called by muse, mutect2, varscan2
- KLHL40 | c.144C>T p.R48= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV55134906; called by muse, mutect2, varscan2
- KLRC2 | c.327G>A p.Q109= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV67900010; called by muse, mutect2, varscan2
- KMT2C | c.10359C>T p.F3453= | Silent (SNP) | VAF 51/203 reads (25%) | catalogued as COSV51449133; called by muse, mutect2, varscan2
- KRT15 | c.1125G>A p.L375= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV54179822; called by muse, mutect2, varscan2
- LBX2 | c.390C>T p.V130= (on ENST00000377566 / NM_001282430.2; = p.V126= on NM_001009812.2) | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV52035522; called by muse, mutect2, varscan2
- LNX2 | c.1617G>A p.L539= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV60336180; called by muse, mutect2, varscan2
- LRP2 | c.12408G>A p.L4136= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as COSV55557175, COSV55567607; called by muse, mutect2
- LRRC37A3 | c.3027C>T p.L1009= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as rs1267427480, COSV58535622; called by muse, mutect2, varscan2
- MARCHF3 | c.399G>A p.L133= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs993354308; called by muse, mutect2
- MINDY1 | c.828C>T p.L276= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs974399071, COSV56499254; called by muse, mutect2, varscan2
- MLX | c.879G>A p.L293= | Silent (SNP) | VAF 57/187 reads (30%) | catalogued as COSV53817511; called by muse, mutect2, varscan2
- MRFAP1L1 | c.81C>T p.F27= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs769175294, COSV57922970, COSV57923177; called by muse, mutect2, varscan2
- MRGPRF | c.111G>A p.Q37= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV57996030; called by muse, mutect2, varscan2
- MS4A7 | c.312C>T p.I104= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV55730060; called by muse, mutect2, varscan2
- MYH1 | c.234C>T p.F78= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as rs757857124, COSV55437422; called by muse, mutect2, varscan2
- NDRG3 | c.387G>A p.L129= (on ENST00000349004 / NM_032013.4; = p.L117= on NM_022477.4) | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV62422145; called by muse, mutect2, varscan2
- NELFA | c.513G>A p.V171= (on ENST00000542778; = p.V160= on NM_005663.5) | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as COSV61606238; called by muse, mutect2, varscan2
- NELL1 | c.1971C>T p.C657= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV54273852; called by muse, mutect2, varscan2
- NLE1 | c.873C>T p.N291= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs1251839144, COSV62604401; called by muse, mutect2, varscan2
- NSD2 | c.3550C>T p.L1184= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV56391845; called by muse, mutect2, varscan2
- NUP155 | c.27G>A p.A9= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1244442616, COSV51527269; called by muse, mutect2, varscan2
- OR1C1 | c.771C>T p.A257= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs755711640, COSV101376172, COSV68715809; called by muse, mutect2, varscan2
- OR2A7 | c.932G>A p.*311= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- OR4C6 | c.585C>T p.L195= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV58604417; called by muse, mutect2, varscan2
- OR4D1 | c.636C>T p.L212= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV52125312; called by muse, mutect2, varscan2
- OR6C2 | c.885G>A p.V295= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs142733366, COSV59515775; called by muse, mutect2, varscan2
- PCDHB8 | c.930C>T p.F310= | Silent (SNP) | VAF 32/313 reads (10%) | catalogued as rs1554281059, COSV50775804; called by muse, mutect2, varscan2
- PIK3C2A | c.4869C>T p.F1623= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV56403667; called by muse, mutect2, varscan2
- PKHD1 | c.11622G>A p.L3874= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV64391959; called by muse, mutect2, varscan2
- PLEKHG7 | c.255G>A p.S85= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs760069582, COSV67337873; called by muse, mutect2, varscan2
- POLR3E | c.135C>G p.L45= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV55401218; called by muse, mutect2, varscan2
- PTPRD | c.3048G>T p.V1016= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV61954100; called by muse, mutect2, varscan2
- RABL6 | c.645G>A p.K215= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV61036464; called by muse, mutect2, varscan2
- RASAL3 | c.1968G>A p.E656= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as rs903684522; called by muse, mutect2
- RHOA | c.581G>A p.*194= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV69042130; called by muse, varscan2
- RNF180 | c.1155G>A p.R385= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV56962563; called by muse, mutect2, varscan2
- RNF213 | c.5868C>T p.L1956= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs777348031, COSV100300820, COSV60399685, COSV60405550; called by muse, mutect2, varscan2
- ROR2 | c.1017G>A p.P339= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs1337548059, COSV65219868; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPA1 | c.147A>T p.G49= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV54609995; called by muse, mutect2, varscan2
- RPA1 | c.666C>T p.F222= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs755486139; called by muse, mutect2
- RYR3 | c.8910G>A p.L2970= (on ENST00000389232; = p.L2971= on NM_001036.6) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV66793612; called by muse, mutect2, varscan2
- SBNO1 | c.3726C>G p.L1242= (on ENST00000420886; = p.L1241= on NM_018183.5) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1447138558; called by muse, mutect2
- SEMA3A | c.69G>A p.Q23= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as COSV54873546; called by muse, mutect2, varscan2
- SEMG2 | c.168T>C p.H56= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV65647556; called by muse, mutect2, varscan2
- SERBP1 | c.681C>T p.V227= (on ENST00000370995 / NM_001018067.2; = p.V221= on NM_015640.4) | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV63413614; called by muse, mutect2, varscan2
- SETX | c.6699C>T p.F2233= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV56386811; called by muse, mutect2, varscan2
- SFMBT2 | c.1224C>T p.F408= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV62810814; called by muse, mutect2, varscan2
- SFTPB | c.273G>A p.T91= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as rs45478492, COSV60893490; called by muse, mutect2, varscan2
- SH2D3C | c.1719C>T p.G573= (on ENST00000314830 / NM_170600.3; = p.G416= on NM_005489.4) | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV59124095; called by muse, mutect2, varscan2
- SLC11A2 | c.1008C>G p.S336= (on ENST00000394904 / NM_001379455.1; = p.S307= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV50371290; called by muse, mutect2, varscan2
- SLC26A5 | c.1971G>A p.V657= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV59702514; called by muse, mutect2, varscan2
- SLC26A6 | c.1776G>A p.Q592= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV56572613; called by muse, mutect2, varscan2
- SLC46A1 | c.651C>T p.A217= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV58708385; called by muse, mutect2, varscan2
- SPATA9 | c.354G>A p.P118= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs776296440, COSV57224413; called by muse, mutect2, varscan2
- SYNE1 | c.23919G>A p.T7973= (on ENST00000367255 / NM_182961.4; = p.T7902= on NM_033071.3) | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs767628258, COSV55003892; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- TAF4B | c.2304G>A p.Q768= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs761931979, COSV52304711; called by muse, mutect2
- TBC1D8 | c.870C>T p.F290= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV65213260; called by muse, mutect2, varscan2
- TPO | c.792G>A p.E264= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV61103367; called by muse, mutect2, varscan2
- TRMT13 | c.1344C>T p.F448= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV61583174; called by muse, mutect2, varscan2
- TTC17 | c.69C>T p.L23= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1449692353, COSV99234549; called by muse, mutect2
- UGT3A1 | c.939C>G p.L313= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV57098844; called by muse, mutect2
- VCX | c.492G>C p.L164= | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as rs1264563900, COSV58232611; called by muse, varscan2
- VSTM1 | c.588C>T p.L196= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV58075203; called by muse, mutect2, varscan2
- WNK4 | c.327G>A p.T109= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV53820959; called by muse, mutect2, varscan2
- ZBTB32 | c.588C>T p.L196= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV52889666; called by muse, mutect2, varscan2
- ZBTB4 | c.972G>C p.L324= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV60980408; called by muse, mutect2, varscan2
- ZNF184 | c.1791G>A p.Q597= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV53004495; called by muse, mutect2, varscan2
- ZNF197 | c.966G>A p.K322= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV60360727, COSV60360822; called by muse, mutect2, varscan2
- ZNF441 | c.285G>A p.E95= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV63540034; called by muse, mutect2, varscan2
- ZNF451 | c.1308T>C p.S436= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV62598003; called by muse, mutect2, varscan2
- ZNF462 | c.3984C>G p.L1328= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV52940628; called by muse, mutect2, varscan2
- ZNF613 | c.1284T>C p.Y428= (on ENST00000293471 / NM_001031721.4; = p.Y392= on NM_024840.4) | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs1301953518, COSV53272320; called by muse, mutect2, varscan2
- AC073310.1 | n.882C>G | RNA (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848269 G>A | 5'Flank (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+98G>A | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs372895407; called by muse, mutect2, varscan2
- MAP4 | c.1999+5246C>T | Intron (SNP) | VAF 46/171 reads (27%) | catalogued as COSV53138484; called by muse, mutect2, varscan2
- RAPGEF5 | chr7:22194019 C>G | 5'Flank (SNP) | VAF 49/204 reads (24%) | catalogued as COSV59784611; called by muse, mutect2, varscan2
- SNORD115-17 | n.34G>C | RNA (SNP) | VAF 68/307 reads (22%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 13/26 reads (50%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
